Somatic mutation profile of tumor specimen BA2760D (aliquot aq-BA2760D) from BEATAML1.0 case 2524, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 54.9 years (20,052 days).
Specimen BA2760D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 307fef74-1de9-485b-9553-20215e380d1a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2383D (Solid Tissue Normal), aliquot aq-BA2383D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c9ea5f00-e813-48f4-853d-755505ac1883

The open-access MAF lists 9 somatic variants for this specimen: 4 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 4, Missense Mutation 4, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCNB3 | c.2030C>T p.S677L | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.966); catalogued as COSV99329927; called by muse, mutect2
- GYPE | c.26T>C p.L9S | Missense Mutation (SNP) | VAF 9/168 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- LRRN4 | c.491G>T p.R164L | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.82); PolyPhen benign (0.01); called by muse, mutect2
- PCDHB16 | c.1008G>T p.Q336H | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.889); called by muse, varscan2
- HDAC8 | c.243G>A p.K81= | Silent (SNP) | VAF 21/68 reads (31%) | called by muse, mutect2, varscan2
- INPP5F | c.823C>A p.R275= | Silent (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- NPFFR2 | c.1203C>T p.Y401= | Silent (SNP) | VAF 42/143 reads (29%) | catalogued as rs538543232, COSV100440247, COSV58146856, COSV58152388; called by muse, mutect2, varscan2
- SND1 | c.1168C>T p.L390= | Silent (SNP) | VAF 11/68 reads (16%) | called by muse, mutect2, varscan2
- NDUFS7 | c.228+351G>A | Intron (SNP) | VAF 10/21 reads (48%) | catalogued as rs369012244; called by muse, varscan2
